Somatic mutation profile of tumor specimen 0DGMHO from CCDI case PBBTNY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.5 years (898 days).
Specimen 0DGMHO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1292eb6-0c4e-42d9-bb4d-27b2473eaf5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGMI1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f17be93-3450-4058-8d5f-91dca3f52635

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF4 | c.875G>A p.S292N | Missense Mutation (SNP) | VAF 240/598 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV51952044; called by muse, mutect2, varscan2
- CLEC1B | c.545+2T>C p.X182_splice | Splice Site (SNP) | VAF 64/146 reads (44%) | catalogued as COSV100046024; called by muse, mutect2, varscan2
- MED12 | c.771G>T p.W257C | Missense Mutation (SNP) | VAF 353/808 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61342992; called by muse, mutect2
- NOS1 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 35/973 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1195781821, COSV57608819; called by muse, mutect2
- ACTL8 | c.851A>T p.E284V | Missense Mutation (SNP) | VAF 266/607 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- CENPF | c.6266T>C p.V2089A | Missense Mutation (SNP) | VAF 34/1286 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2
- DNAI1 | c.354A>C p.G118= | Silent (SNP) | VAF 203/495 reads (41%) | called by muse, mutect2, varscan2
- SLC38A10 | c.1809G>A p.L603= | Silent (SNP) | VAF 115/345 reads (33%) | called by muse, mutect2, varscan2
- MYORG | c.-19C>T | 5'UTR (SNP) | VAF 112/539 reads (21%) | called by muse, mutect2, varscan2
